Somatic mutation profile of tumor specimen TCGA-66-2756-01A (aliquot TCGA-66-2756-01A-01W-0877-08) from TCGA case TCGA-66-2756, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.3 years (24,929 days).
Specimen TCGA-66-2756-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf92466f-5215-40c5-b020-56337c44fe94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2756-11A (Solid Tissue Normal), aliquot TCGA-66-2756-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fda92722-5596-475f-96e5-19e0f8ff36b1

The open-access MAF lists 536 somatic variants for this specimen: 413 protein-altering or splice-affecting, 110 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 346, Silent 110, Nonsense Mutation 29, Frame Shift Del 14, Splice Site 12, RNA 7, Frame Shift Ins 6, Intron 4, Splice Region 3, Translation Start Site 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 100/125 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1849C>A p.P617T | Missense Mutation (SNP) | VAF 275/1322 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV55295818; called by muse, mutect2, varscan2
- ABCC12 | c.2768T>A p.L923Q | Missense Mutation (SNP) | VAF 112/207 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60916691, COSV60918961; called by muse, mutect2, varscan2
- AC126283.2 | c.1517A>C p.K506T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.625); catalogued as COSV67099454; called by muse, mutect2, varscan2
- ACP7 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | catalogued as rs771107190, COSV58700387; called by muse, mutect2, varscan2
- ACSF3 | c.757G>T p.A253S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.565); catalogued as COSV58080564; called by muse, mutect2, varscan2
- ACTA1 | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 156/196 reads (80%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV64203845, COSV64204093; called by muse, varscan2
- ACTRT2 | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65760072; called by muse, varscan2
- ADCY4 | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV60256432; called by muse, mutect2, varscan2
- ADGRL3 | c.2451C>A p.N817K (on ENST00000506720 / NM_001322402.2; = p.N749K on NM_015236.6) | Missense Mutation (SNP) | VAF 139/708 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759192439, COSV72231449; called by muse, mutect2, varscan2
- AGBL2 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54094326; called by muse, mutect2, varscan2
- AKNA | c.2496G>T p.E832D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV56314173; called by muse, mutect2, varscan2
- AMER3 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201458012, COSV58468822; called by muse, mutect2, varscan2
- ANKRD46 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV59515376; called by muse, mutect2
- ANKS1B | c.2581G>T p.G861W (on ENST00000547776 / NM_152788.4; = p.G87W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60372182; called by muse, mutect2, varscan2
- ANO3 | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV56802042; called by muse, mutect2, varscan2
- ANXA13 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 122/1456 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51621751, COSV51625538; called by muse, mutect2
- ARAP2 | c.2573G>T p.G858V | Missense Mutation (SNP) | VAF 72/275 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs112661490, COSV58290101; called by muse, mutect2, varscan2
- ARAP2 | c.2572G>T p.G858W | Missense Mutation (SNP) | VAF 70/273 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1465728044, COSV58282016, COSV58291868; called by muse, mutect2, varscan2
- ARHGAP25 | c.142A>G p.I48V (on ENST00000409202 / NM_001007231.3; = p.I41V on NM_014882.3) | Missense Mutation (SNP) | VAF 201/795 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1406148808, COSV54906079; called by muse, mutect2, varscan2
- ARID1A | c.6572G>T p.S2191I | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61384742; called by muse, mutect2, varscan2
- ARID1B | c.2913del p.N971Kfs*6 | Frame Shift Del (DEL) | VAF 46/206 reads (22%) | catalogued as COSV51671981; called by mutect2, pindel, varscan2
- ARID2 | c.3592C>G p.P1198A | Missense Mutation (SNP) | VAF 87/138 reads (63%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs757713971, COSV57606539; called by muse, mutect2, varscan2
- ASXL1 | c.3934G>T p.A1312S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV60116208; called by muse, mutect2, varscan2
- ATP1B3 | c.328C>A p.L110I | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV53951066; called by muse, mutect2, varscan2
- BAZ2B | c.3388G>T p.D1130Y | Missense Mutation (SNP) | VAF 81/540 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54276453; called by muse, mutect2, varscan2
- BCAN | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 55/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61257853, COSV61258565; called by muse, mutect2, varscan2
- BCAN | c.2204T>G p.I735S | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV61258581; called by muse, mutect2, varscan2
- BEND3 | c.2073dup p.E692Rfs*21 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs782172473; called by pindel, varscan2
- BIRC6 | c.11890G>T p.V3964L | Missense Mutation (SNP) | VAF 95/135 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV101428306, COSV70203696; called by muse, mutect2, varscan2
- BMP5 | c.1010G>C p.R337T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV63705218, COSV63706208; called by muse, mutect2, varscan2
- BRCA1 | c.1544A>T p.E515V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as CM984015, COSV58796043; called by muse, mutect2, varscan2
- C10orf90 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV52955357; called by muse, mutect2, varscan2
- C14orf39 | c.1062G>T p.L354F | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58783934; called by muse, mutect2, varscan2
- C20orf141 | c.322G>C p.G108R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63028425; called by muse, mutect2, varscan2
- C3orf20 | c.2284G>T p.D762Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53787908; called by muse, mutect2, varscan2
- C9orf131 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 181/1659 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs1395066747, COSV56612976; called by muse, mutect2, varscan2
- C9orf78 | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV59617132; called by muse, mutect2, varscan2
- CACNA1C | c.3955del p.E1319Kfs*19 | Frame Shift Del (DEL) | VAF 26/169 reads (15%) | catalogued as COSV59720075; called by mutect2, pindel, varscan2
- CACNA1D | c.4720C>T p.R1574W (on ENST00000350061 / NM_001128840.3; = p.R1594W on NM_000720.4) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55442346; called by muse, varscan2
- CACNA1E | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1341812213, COSV62409726; called by muse, mutect2, varscan2
- CACUL1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as rs1387831702, COSV100432739, COSV60996091; called by muse, mutect2
- CAMTA1 | c.2484G>C p.Q828H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV57918201; called by muse, mutect2
- CATSPERG | c.3141C>G p.N1047K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV53051973; called by muse, mutect2, varscan2
- CCDC27 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1194019983, COSV53902212; called by muse, mutect2
- CCDC88A | c.5317C>A p.P1773T (on ENST00000436346 / NM_001365480.1; = p.P1745T on NM_018084.5) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1386165718, COSV55067179; called by muse, mutect2, varscan2
- CCDC88A | c.3584A>G p.H1195R | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1176689504, COSV55067195; called by mutect2, varscan2
- CDH11 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763336652, COSV51763225, COSV99217174; called by muse, mutect2, varscan2
- CDH17 | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50335637; called by muse, mutect2
- CDH20 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 178/219 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV53015019; called by muse, mutect2, varscan2
- CDK15 | c.781G>T p.V261L (on ENST00000652192 / NM_001366386.2; = p.V210L on NM_139158.2) | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV53636913, COSV53637977; called by muse, mutect2, varscan2
- CDKL2 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV56734737; called by muse, mutect2, varscan2
- CHCHD6 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.875); catalogued as COSV52066776; called by muse, mutect2, varscan2
- CHRM5 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 285/381 reads (75%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.897); catalogued as COSV67248130; called by muse, mutect2, varscan2
- CILP | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 46/60 reads (77%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1473157143, COSV56026704; called by muse, mutect2, varscan2
- CLEC11A | c.32T>A p.V11E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV51574685; called by muse, mutect2, varscan2
- CNTN5 | c.659C>A p.P220Q | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs778708984, COSV99671225; called by muse, mutect2, varscan2
- COL11A1 | c.3616C>G p.P1206A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV62191210; called by muse, varscan2
- COL1A2 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 93/178 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070785, CM1211689, CM158272, COSV51960043, COSV51963209; called by muse, mutect2, varscan2
- COL24A1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as COSV65310802; called by muse, mutect2, varscan2
- COL9A1 | c.559G>T p.V187L | Missense Mutation (SNP) | VAF 132/246 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs773143381, COSV61833606, COSV61835935; called by muse, mutect2, varscan2
- CPT1A | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1451283997; called by muse, mutect2
- CRACD | c.1934C>T p.A645V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs1242728988, COSV51727802; called by muse, varscan2
- CRB1 | c.1312T>A p.C438S | Missense Mutation (SNP) | VAF 159/218 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66332311; called by muse, mutect2, varscan2
- CRY2 | c.1667C>G p.P556R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as COSV69888955; called by muse, mutect2, varscan2
- CRYBA4 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398882909, COSV61322573; called by muse, mutect2, varscan2
- CSMD3 | c.9197C>A p.S3066Y (on ENST00000297405 / NM_001363185.1; = p.S2897Y on NM_052900.3) | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.74); catalogued as COSV52266974; called by muse, mutect2
- CSMD3 | c.8437C>A p.L2813I (on ENST00000297405 / NM_001363185.1; = p.L2644I on NM_052900.3) | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV52216372; called by muse, mutect2
- CSMD3 | c.6583del p.H2195Mfs*41 (on ENST00000297405 / NM_001363185.1; = p.H2091Mfs*41 on NM_052900.3) | Frame Shift Del (DEL) | VAF 176/252 reads (70%) | catalogued as COSV52188919; called by mutect2, pindel*, varscan2
- CUBN | c.9191G>A p.C3064Y | Missense Mutation (SNP) | VAF 189/353 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1279726638, COSV64723093; called by muse, mutect2, varscan2
- CYP2F1 | c.1036A>T p.M346L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV58528468; called by muse, mutect2, varscan2
- DBP | c.712C>G p.Q238E | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV50033764; called by muse, mutect2, varscan2
- DCAF5 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 141/250 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.705); catalogued as COSV58462037; called by muse, mutect2, varscan2
- DCDC2B | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52210481; called by muse, mutect2, varscan2
- DDC | c.1301A>T p.H434L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.266); catalogued as COSV63566807; called by muse, mutect2, varscan2
- DENND1A | c.619C>T p.L207= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as rs1350738804, COSV65330282; called by muse, mutect2
- DENND1A | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs757822190, COSV65330302; called by muse, mutect2, varscan2
- DHX38 | c.3298C>T p.H1100Y | Missense Mutation (SNP) | VAF 195/254 reads (77%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV51699886; called by muse, mutect2, varscan2
- DISC1 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 97/145 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV64109878; called by muse, mutect2, varscan2
- DKK4 | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV55183252, COSV55184356; called by muse, mutect2, varscan2
- DNAH17 | c.1600C>G p.R534G | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67759047; called by muse, mutect2, varscan2
- DNAH9 | c.12390C>A p.Y4130* | Nonsense Mutation (SNP) | VAF 87/99 reads (88%) | catalogued as COSV52366451; called by muse, mutect2, varscan2
- DNER | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59166920, COSV59172585; called by muse, mutect2, varscan2
- DNMBP | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.258); catalogued as COSV60630351; called by muse, mutect2, varscan2
- DOCK10 | c.5223A>C p.K1741N | Missense Mutation (SNP) | VAF 144/449 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51423123; called by muse, mutect2, varscan2
- DPF3 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299081470, COSV100818372; called by muse, mutect2, varscan2
- EDNRB | c.1433T>A p.L478* (on ENST00000377211 / NM_001201397.1; = p.L388* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 90/114 reads (79%) | catalogued as CD101992, COSV57526346; called by muse, mutect2, varscan2
- EHF | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 167/439 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57669390; called by muse, mutect2, varscan2
- EMID1 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 7/8 reads (88%) | catalogued as COSV61830427; called by muse, mutect2, varscan2
- EML3 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV53873703; called by muse, mutect2, varscan2
- ENOPH1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV56731780; called by muse, varscan2
- ENPEP | c.2737G>T p.A913S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.056); catalogued as COSV54455157; called by muse, mutect2, varscan2
- ENTHD1 | c.1569G>C p.Q523H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771623941, COSV57323348; called by muse, mutect2, varscan2
- EOGT | c.1331A>T p.E444V (on ENST00000383701 / NM_001278689.2; = p.E360V on NM_173654.3) | Missense Mutation (SNP) | VAF 89/225 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152962; called by muse, mutect2, varscan2
- ERICH1 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV50640022; called by muse, mutect2, varscan2
- EYA1 | c.1310G>C p.R437P | Missense Mutation (SNP) | VAF 95/612 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV58165306, COSV58169645; called by muse, mutect2, varscan2
- FAM117B | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57421056; called by muse, mutect2, varscan2
- FAM167B | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV100406014, COSV61110453; called by muse, mutect2, varscan2
- FASTKD1 | c.817A>T p.S273C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV70007132; called by muse, mutect2, varscan2
- FAT3 | c.9340C>A p.Q3114K | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV53152906; called by muse, mutect2, varscan2
- FAT4 | c.7541A>T p.K2514I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV104405579, COSV58700645; called by muse, mutect2, varscan2
- FGF5 | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56891370; called by muse, mutect2, varscan2
- FLG | c.10704G>T p.Q3568H | Missense Mutation (SNP) | VAF 309/742 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.837); catalogued as COSV64245726; called by muse, mutect2, varscan2
- FMNL3 | c.630G>T p.R210S | Missense Mutation (SNP) | VAF 40/450 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV53301551; called by muse, mutect2
- FOXR1 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1451849512, COSV57651917, COSV57653280; called by muse, mutect2, varscan2
- FREM1 | c.6089T>C p.L2030P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66527461; called by muse, mutect2, varscan2
- FRYL | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 38/169 reads (22%) | catalogued as COSV51956403; called by muse, mutect2, varscan2
- FSHR | c.2066T>C p.L689P | Missense Mutation (SNP) | VAF 107/498 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs547208879, COSV58630502; called by muse, mutect2, varscan2
- FUT9 | c.975T>A p.N325K | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56152914; called by muse, mutect2, varscan2
- GABRB3 | c.1363G>C p.V455L | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV54657264, COSV54676874; called by muse, mutect2, varscan2
- GAD1 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV100713809, COSV60153550; called by muse, mutect2, varscan2
- GALC | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54328507; called by muse, mutect2, varscan2
- GDF5 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 35/64 reads (55%) | catalogued as COSV65502719; called by muse, mutect2, varscan2
- GEN1 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 214/381 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58057918; called by muse, mutect2, varscan2
- GGA2 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs768112093, COSV100564454; called by muse, mutect2, varscan2
- GGT1 | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV50643396; called by muse, varscan2
- GLA | c.518A>G p.Y173C | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV54510177; called by muse, mutect2, varscan2
- GNB3 | c.431-2A>T p.X144_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | catalogued as COSV51835228; called by muse, mutect2, varscan2
- GNG4 | c.75G>T p.M25I | Missense Mutation (SNP) | VAF 144/226 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV64000062; called by muse, varscan2
- GP1BA | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 39/46 reads (85%) | SIFT deleterious (0); catalogued as rs1219496797, COSV56700366; called by muse, mutect2, varscan2
- GPRC6A | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV59954977; called by muse, mutect2, varscan2
- GRHPR | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 107/374 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57041155; called by muse, varscan2
- GRIN2A | c.3635C>A p.T1212K | Missense Mutation (SNP) | VAF 486/992 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as rs1042202486, COSV58023346, COSV58023466; called by muse, varscan2
- GRIN2D | c.1900T>C p.W634R | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54381259; called by muse, mutect2, varscan2
- GTF3C1 | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 104/215 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62243556, COSV62244168; called by muse, mutect2, varscan2
- H6PD | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1261176865, COSV101072427, COSV66231840; called by muse, mutect2, varscan2
- HEMGN | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52327574; called by muse, mutect2, varscan2
- HGF | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.592); catalogued as rs1396522967, COSV55954206; called by muse, mutect2, varscan2
- HOGA1 | c.701-2A>C p.X234_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV65706590; called by muse, mutect2, varscan2
- HOXB1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1023657929, COSV53318252; called by muse, mutect2
- HPS1 | c.251A>T p.H84L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV57269518; called by muse, mutect2, varscan2
- HTRA1 | c.1179C>A p.S393R | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as COSV64564932; called by muse, mutect2, varscan2
- ICA1 | c.1242G>T p.E414D | Missense Mutation (SNP) | VAF 214/361 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV55582162; called by muse, mutect2, varscan2
- ICOS | c.577A>G p.R193G | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1361045875, COSV57030654; called by muse, mutect2, varscan2
- IFI44 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 27/460 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66075326; called by muse, mutect2
- IGHD | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV66655363; called by muse, mutect2, varscan2
- IGKV2-24 | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1234385391; called by muse, mutect2, varscan2
- IGKV3-15 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 78/450 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs530316441; called by muse, mutect2
- IKZF1 | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as rs1397682553, COSV100497793; called by muse, mutect2
- IL1RAPL1 | c.1291C>A p.L431I | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56275995; called by muse, mutect2, varscan2
- INTS5 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV57952927; called by muse, mutect2, varscan2
- IPO9 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1295709724, COSV64234944; called by muse, mutect2, varscan2
- IQGAP2 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 98/154 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.041); catalogued as COSV57178523; called by muse, mutect2, varscan2
- ITGAM | c.1583T>A p.L528Q (on ENST00000648685 / NM_001145808.2; = p.L527Q on NM_000632.4) | Missense Mutation (SNP) | VAF 125/399 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54940499; called by muse, mutect2, varscan2
- KANK2 | c.2215G>C p.G739R (on ENST00000586659 / NM_001379562.1; = p.G747R on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62009234; called by muse, mutect2, varscan2
- KATNIP | c.2579A>C p.D860A | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as COSV55188182; called by muse, mutect2, varscan2
- KCNH4 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.036); catalogued as rs1402380822, COSV52920073; called by muse, mutect2, varscan2
- KCNH7 | c.1678G>T p.A560S | Missense Mutation (SNP) | VAF 224/279 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV59807344; called by muse, mutect2, varscan2
- KCNH8 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs1447395084, COSV60471990; called by muse, mutect2, varscan2
- KCNS2 | c.248A>G p.H83R | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV54640028; called by muse, mutect2, varscan2
- KCNT1 | c.403T>C p.S135P (on ENST00000488444; = p.S154P on NM_020822.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV53707324; called by muse, mutect2, varscan2
- KDM6B | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs761175532, COSV54684847; called by muse, mutect2, varscan2
- KDM7A | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50093991; called by muse, mutect2, varscan2
- KEL | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 306/588 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as COSV62336829; called by muse, mutect2, varscan2
- KIAA0100 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV66495318, COSV66495454; called by muse, mutect2, varscan2
- KIAA0100 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.086); catalogued as COSV66495460; called by muse, mutect2, varscan2
- KIAA0319 | c.2350G>T p.G784W | Missense Mutation (SNP) | VAF 93/128 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746459020, COSV65501020; called by muse, mutect2, varscan2
- KIAA0319 | c.2349G>T p.E783D | Missense Mutation (SNP) | VAF 97/132 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs770651150, COSV65496309, COSV65501026; called by muse, mutect2, varscan2
- KIR3DL1 | c.1222C>A p.Q408K | Missense Mutation (SNP) | VAF 333/829 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as rs1209079555, COSV58494531; called by muse, mutect2, varscan2
- KLHL40 | c.1063G>T p.V355F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV55136395; called by muse, mutect2
- KRTAP19-5 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 299/615 reads (49%) | catalogued as rs761244768, COSV61859339; called by muse, varscan2
- KRTAP19-5 | c.159T>A p.Y53* | Nonsense Mutation (SNP) | VAF 300/623 reads (48%) | catalogued as COSV61859343; called by muse, varscan2
- KRTAP3-3 | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 169/349 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV66956744; called by muse, mutect2, varscan2
- L3MBTL3 | c.701G>T p.W234L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399961435, COSV62387858; called by muse, mutect2, varscan2
- LAMA1 | c.8950A>G p.K2984E | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67541516; called by muse, mutect2, varscan2
- LAMB1 | c.1732G>T p.D578Y | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV55968423; called by muse, mutect2, varscan2
- LAMC1 | c.4441G>T p.D1481Y | Missense Mutation (SNP) | VAF 304/445 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1265527713, COSV51160897; called by muse, mutect2, varscan2
- LDB2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1277170300, COSV58765241, COSV58766021; called by muse, mutect2, varscan2
- LEPR | c.72G>T p.L24F | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV60760585; called by muse, mutect2, varscan2
- LGI2 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV66123067, COSV66123651; called by muse, mutect2, varscan2
- LHX2 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1195957735, COSV65318880; called by muse, mutect2, varscan2
- LMOD3 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV70456477; called by muse, mutect2, varscan2
- LRP1B | c.10957G>A p.D3653N | Missense Mutation (SNP) | VAF 810/1097 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV67255752; called by muse, mutect2, varscan2
- LRP1B | c.9944C>G p.S3315C | Missense Mutation (SNP) | VAF 203/289 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257792, COSV67255758; called by muse, mutect2, varscan2
- LRP4 | c.3604C>T p.R1202C | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1460217409, COSV66134603; called by muse, mutect2, varscan2
- LRRC7 | c.1507G>C p.D503H (on ENST00000651989 / NM_001370785.2; = p.D470H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50548169, COSV50647007; called by muse, mutect2, varscan2
- LRRC71 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV59356712; called by muse, mutect2
- LRRTM3 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 365/550 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100791407; called by muse, varscan2
- LTBP2 | c.5079C>A p.N1693K | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.154); catalogued as COSV56211757; called by muse, mutect2, varscan2
- M1AP | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 162/363 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51847141; called by muse, mutect2, varscan2
- MAGEA11 | c.208G>T p.A70S | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.291); catalogued as COSV60757570; called by muse, mutect2, varscan2
- MAGEB1 | c.1033C>A p.H345N | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV66776292; called by muse, mutect2, varscan2
- MAL2 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 141/1287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52662333; called by muse, mutect2, varscan2
- MAST1 | c.1008A>T p.P336= | Splice Region (SNP) | VAF 20/25 reads (80%) | catalogued as COSV52251774; called by muse, mutect2, varscan2
- MBIP | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV59254870; called by muse, mutect2, varscan2
- MCM3AP | c.3807C>A p.C1269* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV52443699, COSV52445821; called by muse, mutect2, varscan2
- MCM9 | c.269T>G p.V90G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV60164930; called by mutect2, varscan2
- MDC1 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1348643374, COSV64526360; called by muse, mutect2, varscan2
- METTL22 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as COSV50838373; called by muse, mutect2, varscan2
- MFSD9 | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV51495104; called by muse, mutect2, varscan2
- MOBP | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 23/88 reads (26%) | PolyPhen possibly damaging (0.522); catalogued as COSV100215420, COSV60655376; called by muse, mutect2, varscan2
- MPEG1 | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); catalogued as COSV57093533; called by muse, mutect2, varscan2
- MRGPRX4 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 109/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58591298; called by muse, mutect2, varscan2
- MRPL11 | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1263589666, COSV60599359; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 55/172 reads (32%) | catalogued as rs768684761; called by pindel, varscan2*
- MTNR1B | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57067944; called by muse, mutect2, varscan2
- MTTP | c.2378A>T p.D793V | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55508633; called by muse, mutect2, varscan2
- MYH7 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 53/86 reads (62%) | catalogued as CM102042, COSV62522034, COSV62522084; called by muse, mutect2, varscan2
- MYO3A | c.1231G>C p.A411P | Missense Mutation (SNP) | VAF 108/206 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56342426; called by muse, mutect2, varscan2
- N4BP1 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV52211654, COSV52212723; called by muse, mutect2, varscan2
- NANOG | c.31T>A p.L11M | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV57552201; called by muse, mutect2, varscan2
- NCR1 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 97/187 reads (52%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52557836; called by muse, mutect2, varscan2
- NEXMIF | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 420/490 reads (86%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as COSV50066359; called by muse, mutect2, varscan2
- NF1 | c.1444A>G p.T482A | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs770201871, COSV62213762; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.7317A>T p.L2439F (on ENST00000358273 / NM_001042492.3; = p.L2418F on NM_000267.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62213774; called by muse, mutect2, varscan2
- NOD1 | c.2564A>G p.E855G | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as COSV56113999; called by muse, mutect2, varscan2
- NPAS4 | c.945-2A>T p.X315_splice | Splice Site (SNP) | VAF 24/47 reads (51%) | catalogued as COSV60651885; called by muse, mutect2, varscan2
- NPAS4 | c.1775C>G p.A592G | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV60648850, COSV60651898; called by muse, mutect2, varscan2
- NPR3 | c.1179G>T p.W393C | Missense Mutation (SNP) | VAF 103/637 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54091265; called by muse, mutect2, varscan2
- NPY2R | c.449G>T p.R150M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV61529116; called by muse, mutect2, varscan2
- NRXN2 | c.2419A>G p.K807E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV55460258; called by muse, mutect2, varscan2
- NUGGC | c.923C>G p.T308S | Missense Mutation (SNP) | VAF 36/47 reads (77%) | SIFT tolerated (0.49); PolyPhen benign (0.1); catalogued as COSV58437714; called by muse, mutect2, varscan2
- NUP160 | c.2743A>T p.R915W | Missense Mutation (SNP) | VAF 208/555 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV65855344; called by muse, mutect2, varscan2
- OGA | c.1196-1G>A p.X399_splice | Splice Site (SNP) | VAF 16/49 reads (33%) | catalogued as COSV63382670; called by muse, mutect2, varscan2
- OR13F1 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 116/412 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV58252265; called by muse, mutect2, varscan2
- OR1D2 | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 147/690 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as COSV58922147; called by muse, mutect2, varscan2
- OR1L8 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV59186989; called by muse, mutect2
- OR52K1 | c.48G>T p.L16F | Missense Mutation (SNP) | VAF 429/1103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1328185342, COSV56904360; called by muse, mutect2, varscan2
- OR56A1 | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 280/661 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57363479, COSV57363943; called by muse, mutect2, varscan2
- OR6C74 | c.409A>T p.R137* | Nonsense Mutation (SNP) | VAF 52/270 reads (19%) | catalogued as COSV59606956; called by muse, mutect2, varscan2
- OR8H1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 49/200 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs537282815, COSV100477436, COSV57295306; called by muse, mutect2, varscan2
- OSBP | c.1326G>T p.E442D | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770322746, COSV55664754; called by muse, mutect2, varscan2
- OSBPL3 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 212/331 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769314791, COSV57660439; called by muse, mutect2, varscan2
- P2RY10 | c.640A>T p.I214F | Missense Mutation (SNP) | VAF 324/398 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1333056124, COSV50684063; called by muse, mutect2, varscan2
- P3H4 | c.1273G>C p.G425R | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV62680093, COSV62680537; called by muse, mutect2, varscan2
- PACC1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 626/1036 reads (60%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV54789010; called by muse, varscan2
- PAPPA2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 334/473 reads (71%) | catalogued as COSV62783233; called by muse, mutect2, varscan2
- PAPPA2 | c.2480A>T p.H827L | Missense Mutation (SNP) | VAF 145/910 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62783238; called by muse, mutect2, varscan2
- PARP1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.076); catalogued as rs1365570270, COSV64691617; called by muse, mutect2
- PAX7 | c.1387G>T p.G463C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs140323790, COSV64751784; called by muse, mutect2, varscan2
- PCDH7 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.353); catalogued as rs1250990524, COSV62341762; called by muse, mutect2
- PCDH7 | c.2417A>C p.K806T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV62341771; called by muse, mutect2
- PCDHA1 | c.1280C>A p.A427E | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65372460, COSV65376044, COSV65376866; called by muse, mutect2, varscan2
- PCDHA8 | c.2341G>A p.G781R | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV65330616; called by muse, mutect2, varscan2
- PCDHB11 | c.1441G>T p.G481C | Missense Mutation (SNP) | VAF 112/143 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61313267; called by muse, mutect2, varscan2
- PCDHB5 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); catalogued as COSV50650226, COSV50661831; called by muse, mutect2, varscan2
- PCDHB7 | c.924C>A p.D308E | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV50798246; called by muse, mutect2, varscan2
- PCMTD2 | c.581A>T p.K194M | Missense Mutation (SNP) | VAF 107/171 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55061628, COSV55062326; called by muse, mutect2, varscan2
- PDE11A | c.1989C>A p.Y663* | Nonsense Mutation (SNP) | VAF 143/444 reads (32%) | catalogued as COSV53703492; called by muse, mutect2, varscan2
- PDLIM5 | c.1650G>T p.M550I | Missense Mutation (SNP) | VAF 81/188 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV58750977; called by muse, mutect2, varscan2
- PDYN | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV99452548, COSV99452966; called by muse, mutect2, varscan2
- PDZD2 | c.4396G>C p.G1466R | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV56867584; called by muse, mutect2, varscan2
- PEAR1 | c.2703C>G p.F901L | Missense Mutation (SNP) | VAF 42/53 reads (79%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1204033646, COSV52774886; called by muse, mutect2, varscan2
- PEG3 | c.4638C>G p.I1546M | Missense Mutation (SNP) | VAF 137/298 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs189053356, COSV55642400; called by muse, mutect2, varscan2
- PHACTR2 | c.1565G>T p.S522I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459231218, COSV59857101; called by muse, mutect2, varscan2
- PKHD1L1 | c.3824T>C p.V1275A | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs200212277, COSV65749244; called by muse, mutect2
- PODXL | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as COSV59872074; called by muse, mutect2, varscan2
- POLR1A | c.4517G>T p.R1506L | Missense Mutation (SNP) | VAF 177/536 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs371198043, COSV55692277; called by muse, mutect2, varscan2
- PPP4R1 | c.2071G>T p.A691S (on ENST00000400556 / NM_001042388.3; = p.A674S on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/162 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53283594; called by muse, mutect2, varscan2
- PPRC1 | c.4856G>T p.R1619L | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV53383618, COSV53387430; called by muse, mutect2, varscan2
- PRCP | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290470, COSV99074701; called by muse, mutect2
- PRDM5 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 135/484 reads (28%) | catalogued as COSV53364734, COSV99309634; called by muse, mutect2, varscan2
- PRKAA2 | c.237-1G>A p.X79_splice | Splice Site (SNP) | VAF 18/94 reads (19%) | catalogued as COSV64805459, COSV64806513; called by muse, mutect2, varscan2
- PRKCSH | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1034713294, COSV52953049; called by muse, mutect2, varscan2
- PRKCZ | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61598865; called by muse, mutect2, varscan2
- PRSS12 | c.1734C>A p.D578E | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.487); catalogued as COSV56608641; called by muse, mutect2, varscan2
- PSG7 | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 246/695 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782418664, COSV68446090; called by muse, mutect2, varscan2
- PTPN13 | c.3001G>T p.G1001* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV57413621; called by muse, mutect2, varscan2
- PTPRO | c.2805C>A p.D935E (on ENST00000281171 / NM_030667.3; = p.D907E on NM_002848.4) | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV55518404; called by muse, mutect2, varscan2
- PTPRU | c.952G>T p.V318L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV60533754; called by muse, mutect2, varscan2
- PXDNL | c.2210T>A p.L737Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1460180117, COSV62494799; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3922A>C p.T1308P | Missense Mutation (SNP) | VAF 68/436 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV56962538; called by muse, mutect2, varscan2
- RAMP2 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV53823393; called by muse, mutect2, varscan2
- RASGEF1B | c.654G>T p.L218= | Splice Region (SNP) | VAF 65/136 reads (48%) | catalogued as rs1480470596, COSV52338731; called by muse, mutect2, varscan2
- RASSF7 | c.253A>G p.R85G | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1191339431, COSV60347998; called by muse, mutect2, varscan2
- RBM25 | c.370G>T p.G124* | Nonsense Mutation (SNP) | VAF 22/101 reads (22%) | catalogued as rs751910088, COSV99998288; called by muse, mutect2
- REG3A | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 135/183 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59410912; called by muse, mutect2, varscan2
- RFWD3 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63098588; called by muse, mutect2
- RFX6 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as CM166833, COSV60587707; called by muse, mutect2, varscan2
- RGS22 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 39/537 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as COSV62665471; called by muse, mutect2
- RHOBTB1 | c.944A>T p.K315M | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV61959567; called by muse, mutect2, varscan2
- RHOJ | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57460459; called by muse, mutect2, varscan2
- RHOT1 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61717575; called by muse, mutect2, varscan2
- RIMS2 | c.1613T>C p.V538A (on ENST00000666250 / NM_001348490.2; = p.V346A on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/488 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51707979; called by muse, mutect2
- RIN3 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 34/124 reads (27%) | catalogued as COSV53653388; called by muse, varscan2
- ROBO1 | c.152A>T p.D51V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.987); catalogued as COSV71972072; called by muse, mutect2, varscan2
- ROS1 | c.3387G>T p.R1129S | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV63859454; called by muse, mutect2, varscan2
- RPRM | c.137C>A p.P46Q | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1258307194, COSV57988833, COSV57989045; called by muse, mutect2, varscan2
- RYR2 | c.13600C>A p.P4534T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs199624074, COSV100772132, COSV63681516; called by muse, mutect2, varscan2
- SASH1 | c.2293A>G p.N765D | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV66564193; called by muse, mutect2, varscan2
- SCG2 | c.1634A>T p.Q545L | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV59541232; called by muse, mutect2, varscan2
- SCN10A | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 46/141 reads (33%) | catalogued as COSV71862355; called by muse, mutect2, varscan2
- SEMA5B | c.2015C>A p.S672* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | catalogued as COSV52090204, COSV52104611; called by muse, mutect2
- SENP7 | c.2106+1G>T p.X702_splice | Splice Site (SNP) | VAF 20/170 reads (12%) | catalogued as COSV58616161; called by muse, varscan2
- SEPTIN14 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377272369, COSV66428343; called by muse, mutect2, varscan2
- SERPINB13 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 19/141 reads (13%) | catalogued as COSV54030230; called by muse, mutect2, varscan2
- SETX | c.2348A>T p.Q783L | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV56391326; called by muse, mutect2, varscan2
- SFRP4 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV52261186; called by muse, mutect2, varscan2
- SFRP4 | c.14T>A p.I5N | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs778293050, COSV52261192; called by muse, mutect2, varscan2
- SIGLEC10 | c.1561T>A p.C521S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59485065; called by muse, mutect2, varscan2
- SIGLEC9 | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.276); catalogued as COSV51586706; called by muse, mutect2, varscan2
- SLC12A1 | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT tolerated (0.53); PolyPhen benign (0.163); catalogued as rs1453165067, COSV66798007; called by muse, mutect2, varscan2
- SLC17A1 | c.218A>G p.Y73C | Missense Mutation (SNP) | VAF 173/208 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1173127916, COSV55081001; called by muse, mutect2, varscan2
- SLC22A13 | c.1655G>C p.*552Sext*85 | Nonstop Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV61291724; called by muse, mutect2, varscan2
- SLC22A8 | c.1594C>A p.L532I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100267904, COSV60324272; called by muse, mutect2, varscan2
- SLC25A24 | c.453C>A p.F151L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV51449586, COSV99916321; called by muse, mutect2, varscan2
- SLC30A8 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 41/371 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV69974289; called by muse, mutect2, varscan2
- SLC39A12 | c.1747C>A p.P583T (on ENST00000377369 / NM_001145195.2; = p.P546T on NM_152725.3) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66201248; called by muse, mutect2, varscan2
- SLC49A4 | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53748590; called by muse, mutect2, varscan2
- SLC4A1AP | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 65/132 reads (49%) | catalogued as rs768833197, COSV58136583; called by muse, mutect2, varscan2
- SLC8A1 | c.262A>C p.M88L | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100245031, COSV60491753; called by muse, mutect2, varscan2
- SLC9A8 | c.1653del p.R552Afs*4 | Frame Shift Del (DEL) | VAF 15/85 reads (18%) | catalogued as COSV64287723, COSV64288092; called by mutect2, pindel, varscan2
- SLCO1B3 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 58/269 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV53943264; called by muse, mutect2, varscan2
- SMC2 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV53962684; called by muse, mutect2, varscan2
- SPATA17 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV65125023; called by muse, mutect2, varscan2
- SPON1 | c.797T>A p.V266E | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as COSV59965300; called by muse, mutect2, varscan2
- SPTLC2 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV53642053; called by muse, mutect2, varscan2
- SRPX2 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV65934199; called by muse, mutect2, varscan2
- ST3GAL1 | c.4G>A p.V2M | Missense Mutation (SNP) | VAF 26/318 reads (8%) | PolyPhen benign (0.003); catalogued as rs373146178; called by muse, mutect2
- ST6GALNAC4 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 17/25 reads (68%) | PolyPhen probably damaging (0.996); catalogued as rs1262075405, COSV59130370; called by muse, mutect2, varscan2
- STEAP3 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs763722603, COSV61527929, COSV61530346; called by muse, mutect2, varscan2
- STRIP2 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs569854698, COSV50806911; called by muse, mutect2, varscan2
- STRN | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55750758; called by muse, mutect2, varscan2
- SYT13 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV50075528; called by muse, mutect2, varscan2
- TAAR5 | c.350T>A p.F117Y | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57799592; called by muse, mutect2, varscan2
- TARS1 | c.1352G>C p.G451A | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54311269; called by muse, mutect2, varscan2
- TBR1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs934590067, COSV67417852, COSV67418790; called by muse, mutect2
- TBX22 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 80/101 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV64787264; called by muse, mutect2, varscan2
- TCHHL1 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 499/761 reads (66%) | catalogued as rs1220555269, COSV64286812; called by muse, mutect2, varscan2
- TCTN1 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 98/145 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV66542116; called by muse, varscan2
- TEAD2 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1411537775, COSV55563109; called by muse, mutect2, varscan2
- TECRL | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs751017715, COSV67086722, COSV67089360; called by muse, mutect2, varscan2
- TECTA | c.6261G>C p.W2087C | Missense Mutation (SNP) | VAF 183/252 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV50764866; called by muse, mutect2, varscan2
- TENM1 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 288/330 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64432201, COSV64439008; called by muse, mutect2, varscan2
- TENT5A | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as COSV60788947; called by muse, mutect2, varscan2
- TG | c.6832A>C p.S2278R | Missense Mutation (SNP) | VAF 34/709 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55081978; called by muse, mutect2
- TGFBR3 | c.2495G>A p.S832N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166579957, COSV53029289; called by muse, mutect2
- THOC5 | c.1259A>C p.Y420S | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV63800163; called by muse, mutect2, varscan2
- TKTL1 | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 142/169 reads (84%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54214122; called by muse, mutect2, varscan2
- TMC1 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 123/444 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52781711; called by muse, mutect2, varscan2
- TMEM202 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1428111031, COSV58983312; called by mutect2, varscan2
- TNMD | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65977568; called by muse, mutect2, varscan2
- TNS1 | c.5064-1G>T p.X1688_splice | Splice Site (SNP) | VAF 35/61 reads (57%) | catalogued as COSV99409557; called by muse, mutect2, varscan2
- TRAV24 | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1388480041; called by muse, mutect2, varscan2
- TRDN | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554258798, COSV62120806, COSV62128895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM2 | c.195G>T p.Q65H (on ENST00000437508; = p.Q92H on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58637165; called by muse, mutect2, varscan2
- TRIM7 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV51248146; called by muse, mutect2, varscan2
- TRPV5 | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 164/512 reads (32%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); catalogued as COSV54688474; called by muse, mutect2, varscan2
- TSPEAR | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 98/166 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs1555921942, COSV59973295; called by mutect2, varscan2
- TTK | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57885676; called by muse, mutect2, varscan2
- TUBGCP2 | c.393G>T p.M131I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1272304331, COSV53307571; called by muse, mutect2, varscan2
- TUT1 | c.1408G>T p.G470C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53471324; called by muse, mutect2, varscan2
- TXLNB | c.1333C>A p.R445S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100624756, COSV64443082; called by muse, mutect2, varscan2
- UACA | c.3148C>G p.L1050V | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV59858284; called by muse, mutect2, varscan2
- UBAC2 | c.919G>A p.E307K (on ENST00000403766 / NM_001144072.2; = p.E272K on NM_177967.4) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756878728, COSV63120254; called by muse, mutect2, varscan2
- UBP1 | c.50A>T p.H17L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV52146928; called by muse, mutect2, varscan2
- UGT2B4 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 92/508 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766283290, COSV100522352, COSV59319326; called by muse, mutect2, varscan2
- UNC79 | c.6706G>A p.A2236T (on ENST00000393151 / NM_001346218.2; = p.A2059T on NM_020818.5) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV56400620; called by muse, mutect2, varscan2
- USH2A | c.8176G>T p.G2726W | Missense Mutation (SNP) | VAF 138/199 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56410196; called by muse, mutect2, varscan2
- USH2A | c.3631G>T p.V1211F | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.361); catalogued as rs778673633, COSV56410209; called by muse, mutect2, varscan2
- USP15 | c.860G>T p.G287V (on ENST00000280377 / NM_001351159.2; = p.G258V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54796373; called by muse, mutect2, varscan2
- USP29 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54145043; called by muse, mutect2, varscan2
- VASH2 | c.723C>A p.H241Q (on ENST00000517399 / NM_001301056.2; = p.H197Q on NM_024749.5) | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55118885; called by muse, mutect2, varscan2
- VPS35 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54480323; called by muse, mutect2, varscan2
- VPS54 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 81/382 reads (21%) | catalogued as COSV55443523; called by muse, mutect2, varscan2
- VSTM2A | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1269913500, COSV68290616; called by muse, mutect2
- VWCE | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs775507197, COSV57114141; called by muse, mutect2
- WDHD1 | c.73G>T p.G25W | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59461334; called by muse, mutect2
- WDR13 | c.1451A>T p.Q484L | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV54332919; called by muse, mutect2, varscan2
- WDR43 | c.1390G>T p.V464F | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as rs779632583, COSV56099490, COSV56100294; called by muse, mutect2, varscan2
- WEE1 | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55198042; called by muse, mutect2, varscan2
- XCL1 | c.62-2A>T p.X21_splice | Splice Site (SNP) | VAF 114/156 reads (73%) | catalogued as COSV63192638; called by muse, mutect2, varscan2
- XCL1 | c.62-1G>T p.X21_splice | Splice Site (SNP) | VAF 121/164 reads (74%) | catalogued as rs778780777, COSV63192644; called by muse, mutect2, varscan2
- XDH | c.2605G>T p.G869W | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65150440; called by muse, mutect2, varscan2
- XKR9 | c.570G>C p.L190F | Missense Mutation (SNP) | VAF 44/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68773326; called by muse, mutect2, varscan2
- YTHDC2 | c.3315G>T p.L1105F | Missense Mutation (SNP) | VAF 355/481 reads (74%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV50748595; called by muse, mutect2, varscan2
- ZBTB7B | c.666G>T p.E222D (on ENST00000292176; = p.E256D on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV52694161; called by muse, mutect2, varscan2
- ZFP91 | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs1190096906, COSV60160988; called by muse, mutect2, varscan2
- ZFPM2 | c.3178C>A p.Q1060K | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as rs201190084, COSV65873832, COSV65875074; called by muse, mutect2, varscan2
- ZFYVE28 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.211); catalogued as COSV52115186; called by muse, mutect2, varscan2
- ZIK1 | c.703G>T p.G235* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV56738034; called by muse, mutect2, varscan2
- ZNF100 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV59749216; called by muse, mutect2, varscan2
- ZNF12 | c.1982A>G p.Y661C (on ENST00000405858 / NM_016265.4; = p.Y623C on NM_006956.3) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61245211; called by muse, mutect2, varscan2
- ZNF121 | c.413A>C p.H138P | Missense Mutation (SNP) | VAF 43/65 reads (66%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); catalogued as COSV57552199; called by muse, mutect2, varscan2
- ZNF230 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 117/362 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV71273613; called by muse, mutect2, varscan2
- ZNF300 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 162/197 reads (82%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV51043030; called by muse, mutect2, varscan2
- ZNF311 | c.1854A>T p.K618N | Missense Mutation (SNP) | VAF 99/116 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV65853275; called by muse, varscan2
- ZNF311 | c.1853A>C p.K618T | Missense Mutation (SNP) | VAF 99/116 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65853277; called by muse, varscan2
- ZNF318 | c.2161C>T p.H721Y | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV58935909; called by muse, varscan2
- ZNF320 | c.256T>A p.C86S | Missense Mutation (SNP) | VAF 169/439 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV67088659; called by muse, mutect2, varscan2
- ZNF331 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV53478787, COSV53480518; called by muse, mutect2, varscan2
- ZNF335 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as rs1457770765, COSV59819314; called by muse, mutect2, varscan2
- ZNF33A | c.1811G>T p.G604V (on ENST00000458705 / NM_006974.3; = p.G605V on NM_006954.2) | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275616, COSV56724376; called by muse, mutect2, varscan2
- ZNF443 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 106/158 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1348150135, COSV100042403, COSV56893267; called by muse, mutect2, varscan2
- ZNF461 | c.1038A>C p.E346D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.024); catalogued as COSV64454618; called by muse, mutect2, varscan2
- ZNF536 | c.1191C>A p.N397K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62830636; called by muse, mutect2, varscan2
- ZNF638 | c.2377+1G>T p.X793_splice | Splice Site (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52493194; called by muse, mutect2, varscan2
- ZNF816 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1306299276, COSV54412190; called by muse, mutect2
- ZSCAN4 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV56594271; called by muse, mutect2, varscan2
- CBWD5 | c.1058G>C p.R353T (on ENST00000382405 / NM_001330668.1; = p.R305T on NM_001024916.3) | Missense Mutation (SNP) | VAF 51/391 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CHD5 | c.1688del p.G563Afs*30 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- CNOT1 | c.119del p.G40Vfs*35 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, pindel, varscan2
- FAM149A | c.1126_1127del p.A377Lfs*7 (on ENST00000356371 / NM_001367768.2; = p.A86Lfs*7 on NM_015398.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by pindel, varscan2
- GRN | c.439dup p.W147Lfs*13 | Frame Shift Ins (INS) | VAF 90/198 reads (45%) | called by mutect2, pindel, varscan2
- HECW1 | c.4615dup p.S1539Kfs*53 | Frame Shift Ins (INS) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- HYDIN | c.11159dup p.N3720Kfs*28 | Frame Shift Ins (INS) | VAF 170/320 reads (53%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 151/368 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- IGHV3-33 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- IGHV4-28 | c.208T>A p.Y70N | Missense Mutation (SNP) | VAF 80/534 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, varscan2
- KRTAP1-3 | c.33_40dup p.C14Ffs*92 | Frame Shift Ins (INS) | VAF 33/145 reads (23%) | called by mutect2, varscan2
- MAPT | c.64del p.D22Tfs*22 | Frame Shift Del (DEL) | VAF 42/113 reads (37%) | called by mutect2, pindel, varscan2
- MCM3AP | c.2250G>T p.K750N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ME3 | c.467+1G>C p.X156_splice | Splice Site (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
- MTRR | c.399dup p.G134Wfs*6 (on ENST00000264668; = p.G107Wfs*6 on NM_002454.3 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 261/489 reads (53%) | called by mutect2, pindel, varscan2
- PEBP1 | c.212del p.P71Rfs*22 | Frame Shift Del (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- POTEH | c.333del p.S112Afs*17 | Frame Shift Del (DEL) | VAF 82/341 reads (24%) | called by pindel, varscan2
- RASSF5 | c.1141del p.L381* | Frame Shift Del (DEL) | VAF 89/331 reads (27%) | called by mutect2, pindel, varscan2
- SRSF11 | c.1070del p.K357Sfs*62 | Frame Shift Del (DEL) | VAF 29/144 reads (20%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 99/485 reads (20%) | called by muse, mutect2, varscan2
- TRGC2 | c.131T>A p.I44K | Missense Mutation (SNP) | VAF 124/221 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- TTN | c.61773_61774del p.Y20592Cfs*3 (on ENST00000591111; = p.Y13168Cfs*3 on NM_003319.4) | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by pindel, varscan2
- UGT3A1 | c.1337C>G p.S446C | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ZNF26 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 194/310 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAR | c.48A>G p.P16= | Silent (SNP) | VAF 84/123 reads (68%) | catalogued as COSV52719093; called by muse, mutect2, varscan2
- ANKS1B | c.1650C>A p.I550= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as rs762515978, COSV61365997; called by muse, mutect2, varscan2
- AQP5 | c.549C>A p.S183= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV53311635; called by muse, mutect2, varscan2
- ARHGAP22 | c.171C>G p.R57= | Silent (SNP) | VAF 59/254 reads (23%) | catalogued as COSV50965552; called by muse, mutect2, varscan2
- ASGR2 | c.327G>T p.T109= | Silent (SNP) | VAF 24/28 reads (86%) | catalogued as rs751054614, COSV54691010, COSV54691536; called by muse, mutect2, varscan2
- ASXL3 | c.4059C>T p.L1353= | Silent (SNP) | VAF 283/352 reads (80%) | catalogued as COSV52474462; called by muse, mutect2, varscan2
- BCL2A1 | c.291T>C p.G97= | Silent (SNP) | VAF 245/338 reads (72%) | catalogued as rs566210172, COSV51213413; called by muse, mutect2, varscan2
- BRD1 | c.1098C>A p.P366= | Silent (SNP) | VAF 31/52 reads (60%) | catalogued as COSV53460174; called by muse, mutect2, varscan2
- BTG1 | c.171C>T p.F57= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV55459562; called by muse, mutect2, varscan2
- C16orf78 | c.735C>T p.H245= | Silent (SNP) | VAF 32/163 reads (20%) | catalogued as rs1214062578, COSV54557716, COSV54558143; called by muse, mutect2, varscan2
- C1QB | c.504C>T p.F168= | Silent (SNP) | VAF 65/236 reads (28%) | catalogued as COSV59245797; called by muse, mutect2, varscan2
- C3orf20 | c.2283G>C p.L761= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV53787900, COSV53788983; called by muse, mutect2, varscan2
- C5orf51 | c.225A>T p.T75= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV67566242; called by muse, mutect2, varscan2
- C7orf57 | c.420C>T p.S140= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs1185187219, COSV62363599; called by muse, mutect2
- CACNA1S | c.1884C>A p.G628= | Silent (SNP) | VAF 205/901 reads (23%) | catalogued as COSV62942251; called by muse, mutect2, varscan2
- CD84 | c.216C>G p.P72= | Silent (SNP) | VAF 444/704 reads (63%) | catalogued as rs749987969, COSV60870042; called by muse, mutect2, varscan2
- CDC45 | c.576A>G p.E192= | Silent (SNP) | VAF 373/481 reads (78%) | catalogued as rs758542881, COSV54247441; called by muse, mutect2, varscan2
- CDH12 | c.261C>T p.G87= | Silent (SNP) | VAF 903/1244 reads (73%) | catalogued as COSV66431627; called by muse, mutect2, varscan2
- CER1 | c.336C>A p.L112= | Silent (SNP) | VAF 37/99 reads (37%) | catalogued as COSV101097707; called by muse, mutect2, varscan2
- CFAP61 | c.2289C>A p.P763= | Silent (SNP) | VAF 141/234 reads (60%) | catalogued as rs774950922, COSV55640857; called by muse, mutect2, varscan2
- CHAT | c.942C>G p.V314= | Silent (SNP) | VAF 79/227 reads (35%) | catalogued as COSV60329917; called by muse, mutect2, varscan2
- CIBAR2 | c.912C>G p.L304= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV50742944; called by muse, mutect2
- CLDN17 | c.648T>A p.L216= | Silent (SNP) | VAF 162/551 reads (29%) | catalogued as COSV54524053; called by muse, mutect2, varscan2
- CLIP4 | c.2079G>T p.R693= | Silent (SNP) | VAF 410/585 reads (70%) | catalogued as COSV60751119; called by muse, mutect2, varscan2
- CNGA3 | c.1368G>C p.V456= | Silent (SNP) | VAF 63/93 reads (68%) | catalogued as COSV55626640; called by muse, mutect2, varscan2
- COL2A1 | c.951C>T p.N317= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs778611011, COSV61532801; called by muse, mutect2, varscan2
- CRHR1 | c.237C>T p.T79= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs976852629, COSV53283374; called by muse, mutect2, varscan2
- CSMD1 | c.6024C>A p.P2008= (on ENST00000520002; = p.P2007= on NM_033225.6) | Silent (SNP) | VAF 33/39 reads (85%) | catalogued as rs779589233, COSV59359618; called by muse, mutect2, varscan2
- CTNNAL1 | c.1428G>T p.V476= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs1312007526, COSV57704541; called by muse, mutect2, varscan2
- CTNND2 | c.1026C>T p.S342= | Silent (SNP) | VAF 34/43 reads (79%) | catalogued as rs377310627; called by muse, mutect2, varscan2
- CTSG | c.544C>A p.R182= | Silent (SNP) | VAF 42/167 reads (25%) | catalogued as COSV99361305; called by muse, mutect2, varscan2
- DAB1 | c.1686G>A p.Q562= (on ENST00000371231; = p.Q529= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 72/220 reads (33%) | catalogued as COSV100976738, COSV64696356; called by muse, mutect2, varscan2
- EVI5 | c.2400G>T p.P800= | Silent (SNP) | VAF 94/353 reads (27%) | catalogued as rs138799860, COSV64829041; called by muse, mutect2, varscan2
- FAM47C | c.90C>T p.F30= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV63727012; called by muse, mutect2, varscan2
- FAT3 | c.12663C>G p.V4221= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV53152931; called by muse, mutect2, varscan2
- FAT4 | c.4608T>A p.A1536= | Silent (SNP) | VAF 84/246 reads (34%) | catalogued as COSV67895250; called by muse, mutect2, varscan2
- FBN1 | c.765G>T p.G255= | Silent (SNP) | VAF 378/502 reads (75%) | catalogued as COSV57325804; called by muse, mutect2, varscan2
- FCGBP | c.12330G>T p.V4110= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1394093700; called by muse, mutect2, varscan2
- FCRL5 | c.2280G>T p.G760= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV100709271, COSV62518176; called by muse, mutect2, varscan2
- FRG2B | c.84C>A p.S28= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as COSV101423485, COSV71043731; called by muse, mutect2
- FTO | c.984A>G p.T328= | Silent (SNP) | VAF 314/450 reads (70%) | catalogued as rs772473287, COSV67113312; called by muse, mutect2, varscan2
- GLP2R | c.552G>T p.V184= | Silent (SNP) | VAF 1195/1555 reads (77%) | catalogued as COSV52325840, COSV99301375; called by muse, mutect2, varscan2
- GRIN2B | c.3201C>T p.T1067= | Silent (SNP) | VAF 52/81 reads (64%) | catalogued as rs929166123, COSV101663248, COSV74207074; called by muse, mutect2, varscan2
- HTR1A | c.528C>A p.R176= | Silent (SNP) | VAF 96/164 reads (59%) | catalogued as COSV60502226; called by muse, mutect2, varscan2
- IGHV3-33 | c.72G>C p.V24= | Silent (SNP) | VAF 25/223 reads (11%) | called by muse, varscan2
- IL1RAPL1 | c.1290C>A p.A430= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as COSV56248936, COSV56285621; called by muse, mutect2, varscan2
- IL23A | c.558C>T p.T186= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs749346594, COSV57336254; called by muse, mutect2
- ISX | c.270C>A p.T90= | Silent (SNP) | VAF 61/326 reads (19%) | catalogued as COSV58087846; called by muse, mutect2, varscan2
- KCNQ2 | c.1101C>A p.V367= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV60437669; called by muse, mutect2, varscan2
- KCNV2 | c.1140C>A p.R380= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs759430990, COSV66057104; called by muse, varscan2
- KCTD5 | c.474C>T p.Y158= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1205255182, COSV57063682; called by muse, mutect2, varscan2
- KIF5C | c.1584C>A p.T528= | Silent (SNP) | VAF 31/204 reads (15%) | catalogued as rs1322695766, COSV68482964; called by muse, mutect2, varscan2
- KRTAP13-1 | c.450C>T p.T150= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as COSV62664033; called by muse, mutect2, varscan2
- LILRA5 | c.321A>G p.T107= | Silent (SNP) | VAF 275/489 reads (56%) | catalogued as COSV56644455; called by muse, mutect2, varscan2
- LILRB2 | c.1374C>T p.H458= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs1191282478, COSV58747393; called by muse, mutect2, varscan2
- LIPI | c.642A>T p.P214= | Silent (SNP) | VAF 53/96 reads (55%) | catalogued as COSV60714671; called by muse, mutect2, varscan2
- MAGEB1 | c.1032C>A p.S344= | Silent (SNP) | VAF 36/56 reads (64%) | catalogued as COSV66776284; called by muse, mutect2, varscan2
- MAGEB6 | c.450A>T p.G150= | Silent (SNP) | VAF 59/81 reads (73%) | catalogued as COSV66872724; called by muse, mutect2, varscan2
- MAP11 | c.930G>A p.L310= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1316888031, COSV57587672; called by muse, mutect2, varscan2
- MARCHF6 | c.1950C>T p.I650= | Silent (SNP) | VAF 652/861 reads (76%) | catalogued as COSV56884851; called by muse, mutect2, varscan2
- MDN1 | c.8088A>T p.A2696= | Silent (SNP) | VAF 134/293 reads (46%) | catalogued as COSV65527161, COSV65527199; called by muse, mutect2, varscan2
- MITF | c.1083G>A p.Q361= (on ENST00000448226 / NM_006722.3; = p.Q261= on NM_000248.4) | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs957632782, COSV58834236; called by muse, mutect2, varscan2
- MMP19 | c.1110C>G p.P370= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV59452464; called by muse, mutect2, varscan2
- MXRA5 | c.6483A>G p.G2161= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs1377844355, COSV54244414; called by muse, mutect2
- MYO10 | c.2211G>A p.R737= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- MYO3B | c.849C>G p.S283= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as COSV58712093; called by muse, mutect2, varscan2
- NMU | c.495G>A p.R165= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV51699510, COSV51701191; called by muse, mutect2, varscan2
- OR10K1 | c.273C>A p.T91= | Silent (SNP) | VAF 172/1235 reads (14%) | catalogued as rs1176719574, COSV56873279; called by muse, mutect2, varscan2
- OR6N1 | c.378C>T p.I126= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs375506841; called by muse, mutect2, varscan2
- OR6Q1 | c.762C>A p.L254= | Silent (SNP) | VAF 357/933 reads (38%) | catalogued as COSV56932793, COSV56933155, COSV56934105; called by muse, mutect2, varscan2
- PAX4 | c.372C>T p.I124= | Silent (SNP) | VAF 33/47 reads (70%) | catalogued as rs267601272, COSV58390324; called by muse, mutect2, varscan2
- PCDHA1 | c.756A>G p.L252= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV65376036; called by muse, mutect2, varscan2
- PCDHGA2 | c.1821C>T p.H607= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV53958836; called by muse, mutect2, varscan2
- PCNX2 | c.3810C>T p.F1270= | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as COSV50786191, COSV50846034; called by muse, mutect2
- PDE10A | c.1830C>A p.I610= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV63102876; called by muse, mutect2, varscan2
- PLEC | c.13212G>T p.L4404= (on ENST00000322810 / NM_201380.4; = p.L4294= on NM_000445.5) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1554670646, COSV59673545; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNMA8B | c.81G>T p.P27= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs1243722566, COSV66536759, COSV66537343; called by muse, mutect2, varscan2
- POU2F1 | c.1416A>G p.A472= (on ENST00000541643 / NM_001365848.1; = p.A495= on NM_002697.4) | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV54822236; called by muse, mutect2, varscan2
- PRKD2 | c.789G>T p.V263= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as COSV52188749; called by muse, mutect2, varscan2
- PTPRH | c.738T>A p.T246= | Silent (SNP) | VAF 83/263 reads (32%) | catalogued as COSV54748314; called by muse, mutect2, varscan2
- RBM25 | c.372A>T p.G124= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV56201811; called by muse, mutect2
- RBMS1 | c.1095C>T p.A365= | Silent (SNP) | VAF 214/369 reads (58%) | catalogued as COSV62355786; called by muse, varscan2
- RELN | c.8298T>C p.S2766= | Silent (SNP) | VAF 36/152 reads (24%) | catalogued as COSV100631802; called by muse, mutect2, varscan2
- RHOJ | c.93C>A p.A31= | Silent (SNP) | VAF 55/233 reads (24%) | catalogued as rs1412279807, COSV100369975; called by muse, mutect2, varscan2
- RIMS2 | c.3951G>T p.V1317= | Silent (SNP) | VAF 21/321 reads (7%) | catalogued as rs1041968821, COSV99153358; called by muse, mutect2
- RIPK4 | c.2190C>T p.H730= (on ENST00000352483; = p.H682= on NM_020639.3) | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV60189542; called by muse, mutect2, varscan2
- RPS4Y2 | c.36T>G p.V12= | Silent (SNP) | VAF 66/72 reads (92%) | catalogued as COSV56488782; called by muse, mutect2, varscan2
- SDK1 | c.5445C>T p.S1815= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV67382168; called by muse, mutect2, varscan2
- SLC10A1 | c.939C>A p.P313= | Silent (SNP) | VAF 46/237 reads (19%) | catalogued as COSV99384120; called by muse, mutect2, varscan2
- SLC35G3 | c.600C>A p.G200= | Silent (SNP) | VAF 77/202 reads (38%) | catalogued as rs147862619; called by muse, mutect2, varscan2
- SLC4A10 | c.2172T>C p.D724= (on ENST00000446997 / NM_001354461.2; = p.D694= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 27/607 reads (4%) | catalogued as COSV55792123; called by muse, mutect2
- SLC7A5 | c.732G>C p.V244= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV55366238; called by muse, mutect2, varscan2
- SLC8A3 | c.213G>T p.G71= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV63518820, COSV63524890; called by muse, mutect2, varscan2
- SPEG | c.5485C>A p.R1829= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV56676440; called by mutect2, varscan2
- SRCAP | c.627G>T p.V209= | Silent (SNP) | VAF 81/159 reads (51%) | catalogued as COSV52678143; called by muse, mutect2, varscan2
- SYNE2 | c.15399G>A p.K5133= | Silent (SNP) | VAF 565/934 reads (60%) | catalogued as COSV59962300; called by muse, mutect2, varscan2
- TG | c.6831C>A p.V2277= | Silent (SNP) | VAF 34/712 reads (5%) | called by muse, mutect2
- TOP2B | c.222A>G p.S74= (on ENST00000264331 / NM_001330700.2; = p.S69= on NM_001068.3) | Silent (SNP) | VAF 59/219 reads (27%) | catalogued as COSV51975392; called by muse, mutect2, varscan2
- TRIM55 | c.180G>A p.P60= | Silent (SNP) | VAF 97/575 reads (17%) | catalogued as rs759862288, COSV52549175; called by muse, mutect2, varscan2
- TRIO | c.5691C>T p.R1897= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV60090534; called by muse, mutect2
- TSEN54 | c.570G>T p.V190= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs1475410580, COSV51383960; called by muse, mutect2, varscan2
- UGT2B4 | c.1143T>C p.Y381= | Silent (SNP) | VAF 125/488 reads (26%) | catalogued as COSV59319315; called by muse, mutect2, varscan2
- VPS72 | c.423A>G p.T141= | Silent (SNP) | VAF 16/119 reads (13%) | catalogued as COSV63167940; called by muse, mutect2, varscan2
- ZBED9 | c.1128A>G p.Q376= | Silent (SNP) | VAF 60/81 reads (74%) | catalogued as rs1395882633, COSV101509443, COSV71729669; called by muse, mutect2, varscan2
- ZBTB38 | c.570A>G p.K190= | Silent (SNP) | VAF 440/552 reads (80%) | catalogued as COSV58543491; called by muse, mutect2, varscan2
- ZFHX4 | c.1329C>T p.N443= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV50574987, COSV51482071; called by muse, mutect2, varscan2
- ZNF382 | c.1377G>T p.T459= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV53086628, COSV53090943; called by muse, mutect2, varscan2
- ZNF560 | c.1545C>T p.P515= | Silent (SNP) | VAF 51/68 reads (75%) | catalogued as COSV56866520; called by muse, mutect2, varscan2
- ZNF622 | c.75G>C p.T25= | Silent (SNP) | VAF 43/263 reads (16%) | catalogued as COSV58074857; called by muse, mutect2, varscan2
- ZNF888 | c.96A>T p.L32= | Silent (SNP) | VAF 99/288 reads (34%) | catalogued as COSV101480802; called by muse, mutect2, varscan2
- ANKRD20A5P | n.286T>C | RNA (SNP) | VAF 17/81 reads (21%) | catalogued as rs1555637281; called by muse, mutect2, varscan2
- CLLU1 | n.1977-931G>T | Intron (SNP) | VAF 501/732 reads (68%) | catalogued as COSV65903325; called by muse, mutect2, varscan2
- DCHS2 | n.7818G>A | RNA (SNP) | VAF 62/205 reads (30%) | catalogued as COSV100601425, COSV61777061; called by muse, mutect2, varscan2
- FAM153CP | chr5:178056184 C>A | 3'Flank (SNP) | VAF 21/30 reads (70%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-34969del | Intron (DEL) | VAF 146/174 reads (84%) | called by mutect2, varscan2
- KLK8 | c.71-113C>A | Intron (SNP) | VAF 33/71 reads (46%) | catalogued as COSV99143859; called by muse, mutect2, varscan2
- NRG1 | c.502+31342G>A | Intron (SNP) | VAF 157/987 reads (16%) | catalogued as rs755795145, COSV99827105; called by muse, mutect2, varscan2
- PARGP1 | n.625C>G | RNA (SNP) | VAF 20/118 reads (17%) | called by mutect2, varscan2
- PCDH11X | n.554C>A | RNA (SNP) | VAF 80/102 reads (78%) | called by muse, mutect2, varscan2
- REXO1L1P | n.8del | RNA (DEL) | VAF 4/40 reads (10%) | catalogued as rs1306989531; called by mutect2, pindel
- RN7SL106P | chr15:23163948 A>G | 5'Flank (SNP) | VAF 9/27 reads (33%) | catalogued as rs946646145; called by mutect2, varscan2
- SNORD114-30 | n.69C>G | RNA (SNP) | VAF 40/194 reads (21%) | called by muse, mutect2, varscan2
- XIST | n.9750A>T | RNA (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
